CGCI case HTMCP-02-06-01037 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/738b27ce-ff96-415f-879a-4595b68a9841

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Dead; Days to death: 372 days (1.0 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Bronchiolo-alveolar carcinoma, non-mucinous: ICD-O-3 morphology code: 8252/3; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Year of diagnosis: 2015; Method of diagnosis: Ultrasound Guided Biopsy; AJCC staging edition: 7th; AJCC clinical T: T4; AJCC clinical N: N3; AJCC clinical M: M1a; AJCC clinical stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 372 days (1.0 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Initial disease status: Initial Diagnosis; Days to treatment start: 8 days; Days to treatment end: 134 days; Number of cycles: 6; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Erlotinib; Initial disease status: Progressive Disease; Days to treatment start: 221 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Radiation Therapy, NOS; adjuvant Radiation Therapy, NOS; Surgery, NOS.

Follow-up (4 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 50; ECOG performance status: 3.
- Days to follow up: 161 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to recurrence: 161 days.
- Days to follow up: 361 days; Disease response: With Tumor.
- Days to follow up: 372 days (1.0 years); Disease response: With Tumor.

Molecular and laboratory tests
- NKX2-1 (IHC): Positive.

Other clinical attributes
- Day 0: Weight: 49.2 kg; Height: 150 cm; BMI: 21.9.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 7; Tobacco smoking quit year: 2014.

Biospecimens (3 samples)
- Sample HTMCP-02-06-01037-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-06-01037-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-06-01037-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Bronchioloalveolar Carcinoma Nonmucinous; Tumor status: With tumor; Tobacco smoking age started: 30; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tobacco smoking pack years smoked: 7.0; Lost to follow-up: No; Tobacco smoking history indicator: 4; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Upper lobe.
- History of disease: HIV status: Negative.
- Primary pathology: Lymph nodes examined: No; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Trucut ultrasound guided biopsy.
- Follow-up form 1: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 1, New tumor event: New tumor event site: Lung; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Carboplatin + Paclitaxel; Pharma adjuvant cycles count: 6; Treatment best response: Clinical Progressive Disease.
- Treatments, Treatment 2: Therapy regimen: Progression; Chemo end reporting period: No; Pharmaceutical regimen: Single Agent Therapy (please specify); Treatment best response: Clinical Progressive Disease.
